Somatic mutation profile of tumor specimen TCGA-24-2262-01A (aliquot TCGA-24-2262-01A-01W-0799-08) from TCGA case TCGA-24-2262, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IIIC; Tumor grade: G3; Age at diagnosis: 57.1 years (20,861 days).
Specimen TCGA-24-2262-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 2e81ed24-6ce7-4810-84c5-07a97484dd17.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-24-2262-11A (Solid Tissue Normal), aliquot TCGA-24-2262-11A-01W-0799-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/2b755298-65c7-4165-964e-913618f885cd

The open-access MAF lists 96 somatic variants for this specimen: 67 protein-altering or splice-affecting, 26 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 61, Silent 26, Nonsense Mutation 3, Splice Site 2, RNA 2, 5'UTR 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.396G>T p.K132N | Missense Mutation (SNP) | VAF 105/133 reads (79%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs866775781, COSV52688381, COSV52705927, COSV52891203, COSV53339296; ClinVar: uncertain significance / likely pathogenic; called by muse, mutect2, varscan2
- ABCA12 | c.6538A>G p.T2180A (on ENST00000272895 / NM_173076.3; = p.T1862A on NM_015657.3) | Missense Mutation (SNP) | VAF 13/156 reads (8%) | SIFT tolerated (0.37); PolyPhen possibly damaging (0.872); catalogued as COSV99792526; called by muse, mutect2
- ALG1 | c.1016A>G p.Q339R | Missense Mutation (SNP) | VAF 13/68 reads (19%) | SIFT tolerated (0.21); PolyPhen benign (0.025); catalogued as COSV52156746; called by muse, mutect2, varscan2
- ANKFY1 | c.3013A>C p.R1005= (on ENST00000341657 / NM_001330063.2; = p.R1006= on NM_016376.5) | Splice Region (SNP) | VAF 58/129 reads (45%) | catalogued as COSV58916008; called by muse, mutect2, varscan2
- ANKRD52 | c.1312T>G p.C438G | Missense Mutation (SNP) | VAF 32/218 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99921676; called by muse, varscan2
- ATP2B2 | c.37A>G p.N13D | Missense Mutation (SNP) | VAF 37/70 reads (53%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.992); catalogued as COSV59492622; called by muse, mutect2, varscan2
- ATP9A | c.2398G>A p.V800M | Missense Mutation (SNP) | VAF 8/27 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.797); catalogued as rs752878306, COSV58764771; called by muse, mutect2, varscan2
- BCORL1 | c.4765G>A p.D1589N | Missense Mutation (SNP) | VAF 266/540 reads (49%) | SIFT deleterious (0.05); PolyPhen benign (0.117); catalogued as rs150455678, COSV99501232; called by muse, mutect2, varscan2
- BICD1 | c.2549G>A p.S850N | Missense Mutation (SNP) | VAF 17/508 reads (3%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.074); catalogued as COSV99863140; called by muse, mutect2
- BNIP5 | c.1447C>T p.R483W | Missense Mutation (SNP) | VAF 79/313 reads (25%) | SIFT tolerated (0.07); PolyPhen benign (0.072); catalogued as rs193920980, COSV71325445; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CEP135 | c.2245A>G p.K749E | Missense Mutation (SNP) | VAF 52/181 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.217); catalogued as COSV57258914; called by muse, mutect2, varscan2
- COL1A2 | c.2527G>A p.A843T | Missense Mutation (SNP) | VAF 78/335 reads (23%) | SIFT tolerated (0.08); PolyPhen benign (0); catalogued as rs112697991; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- COL8A1 | c.1832C>T p.P611L | Missense Mutation (SNP) | VAF 6/88 reads (7%) | SIFT tolerated (0.25); PolyPhen benign (0.003); catalogued as COSV53738737, COSV99658650; called by muse, mutect2
- CYB5R1 | c.586C>T p.R196W | Missense Mutation (SNP) | VAF 27/33 reads (82%) | SIFT deleterious (0); PolyPhen possibly damaging (0.885); catalogued as rs777291289, COSV65916873; called by muse, mutect2, varscan2
- DAAM2 | c.1355G>A p.R452Q | Missense Mutation (SNP) | VAF 58/161 reads (36%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.968); catalogued as rs377282686; called by muse, mutect2, varscan2
- DCUN1D1 | c.389+1G>T p.X130_splice | Splice Site (SNP) | VAF 43/209 reads (21%) | catalogued as COSV53044060, COSV99490117; called by muse, mutect2, varscan2
- DHRS13 | c.862G>A p.E288K | Missense Mutation (SNP) | VAF 14/65 reads (22%) | SIFT tolerated (1); PolyPhen benign (0.027); catalogued as rs1181719755, COSV66683842; called by muse, mutect2, varscan2
- DNAH11 | c.11988G>C p.K3996N | Missense Mutation (SNP) | VAF 9/10 reads (90%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.783); catalogued as COSV60948170; called by muse, mutect2, varscan2
- DYNC1H1 | c.8637+2T>A p.X2879_splice | Splice Site (SNP) | VAF 48/183 reads (26%) | catalogued as COSV64135420; called by muse, mutect2, varscan2
- EMSY | c.1513G>A p.G505S | Missense Mutation (SNP) | VAF 38/305 reads (12%) | SIFT tolerated (0.09); PolyPhen benign (0.388); catalogued as COSV100596141; called by muse, mutect2, varscan2
- ENTPD3 | c.885C>A p.S295R | Missense Mutation (SNP) | VAF 10/177 reads (6%) | SIFT tolerated (0.55); PolyPhen benign (0.003); catalogued as COSV100089152; called by muse, mutect2
- FER1L6 | c.5252G>A p.R1751H | Missense Mutation (SNP) | VAF 266/690 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs764812791, COSV67548995; called by muse, varscan2
- FMN2 | c.2954G>C p.G985A | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.049); catalogued as rs141912031, COSV60419013; called by muse, varscan2
- GALNT10 | c.881A>G p.Y294C | Missense Mutation (SNP) | VAF 10/262 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1479217607, COSV99770079; called by muse, mutect2
- GJA8 | c.287C>T p.A96V | Missense Mutation (SNP) | VAF 36/186 reads (19%) | SIFT tolerated (0.79); PolyPhen probably damaging (0.945); catalogued as COSV53788374; called by muse, mutect2, varscan2
- GRIK5 | c.185G>A p.R62Q | Missense Mutation (SNP) | VAF 32/72 reads (44%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.526); catalogued as rs760296333, COSV53476619; called by muse, mutect2, varscan2
- HIVEP1 | c.4931T>A p.V1644D | Missense Mutation (SNP) | VAF 118/341 reads (35%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.915); catalogued as COSV65100014; called by muse, mutect2, varscan2
- HNRNPM | c.1418G>T p.G473V | Missense Mutation (SNP) | VAF 30/123 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.108); catalogued as COSV55314676, COSV99725922; called by muse, mutect2, varscan2
- IGSF9B | c.3274C>A p.P1092T | Missense Mutation (SNP) | VAF 9/25 reads (36%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.055); catalogued as COSV58065461; called by muse, mutect2, varscan2
- INTS10 | c.1473G>T p.E491D | Missense Mutation (SNP) | VAF 22/158 reads (14%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.98); catalogued as COSV67603905; called by muse, mutect2, varscan2
- IQCA1 | c.191T>C p.V64A | Missense Mutation (SNP) | VAF 8/135 reads (6%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.611); catalogued as COSV99610555; called by muse, mutect2
- IRS4 | c.2563G>T p.A855S | Missense Mutation (SNP) | VAF 24/344 reads (7%) | SIFT tolerated (0.36); PolyPhen benign (0.001); catalogued as COSV100929814; called by muse, mutect2
- KCNH5 | c.137G>T p.G46V | Missense Mutation (SNP) | VAF 133/208 reads (64%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV59755961; called by muse, mutect2, varscan2
- KLHL5 | c.2202G>T p.E734D | Missense Mutation (SNP) | VAF 5/81 reads (6%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.996); catalogued as COSV99786073; called by muse, mutect2
- LOXL3 | c.946G>C p.G316R | Missense Mutation (SNP) | VAF 10/29 reads (34%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV51206660; called by muse, mutect2, varscan2
- NEK6 | c.797A>G p.Y266C | Missense Mutation (SNP) | VAF 45/110 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV57216634; called by muse, mutect2, varscan2
- NLRC3 | c.2746C>G p.L916V | Missense Mutation (SNP) | VAF 8/13 reads (62%) | SIFT tolerated (0.56); PolyPhen benign (0.013); catalogued as rs1321464696, COSV57089085; called by muse, mutect2, varscan2
- NR3C2 | c.785C>A p.S262* | Nonsense Mutation (SNP) | VAF 10/208 reads (5%) | catalogued as COSV100679931; called by muse, mutect2
- OR5V1 | c.887A>G p.D296G | Missense Mutation (SNP) | VAF 231/587 reads (39%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.908); catalogued as COSV65827021; called by muse, mutect2, varscan2
- PDP1 | c.1553T>G p.I518S | Missense Mutation (SNP) | VAF 40/163 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV52600748; called by muse, mutect2, varscan2
- PLCB4 | c.3350A>G p.K1117R | Missense Mutation (SNP) | VAF 10/267 reads (4%) | SIFT tolerated (0.42); PolyPhen possibly damaging (0.899); catalogued as COSV53817341, COSV99597206; called by muse, mutect2
- PPRC1 | c.3415C>T p.R1139C | Missense Mutation (SNP) | VAF 37/53 reads (70%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.007); catalogued as rs371010227, COSV53386473; called by muse, mutect2, varscan2
- PRPF31 | c.594C>A p.N198K | Missense Mutation (SNP) | VAF 8/158 reads (5%) | SIFT tolerated (0.07); PolyPhen benign (0.18); catalogued as COSV100320147; called by muse, mutect2
- RP1L1 | c.4864C>T p.R1622W | Missense Mutation (SNP) | VAF 9/10 reads (90%) | SIFT deleterious (0); PolyPhen possibly damaging (0.781); catalogued as rs201695025; called by muse, mutect2, varscan2
- RPS27A | c.313T>C p.Y105H | Missense Mutation (SNP) | VAF 15/42 reads (36%) | SIFT tolerated (0.07); PolyPhen benign (0.031); catalogued as COSV55050856; called by muse, mutect2, varscan2
- SDAD1 | c.806T>C p.V269A | Missense Mutation (SNP) | VAF 97/253 reads (38%) | SIFT tolerated (0.48); PolyPhen benign (0.007); catalogued as COSV62402472; called by muse, mutect2, varscan2
- SHANK1 | c.2593C>T p.H865Y | Missense Mutation (SNP) | VAF 13/32 reads (41%) | SIFT tolerated (1); PolyPhen possibly damaging (0.775); catalogued as rs1283301101, COSV99522244; called by muse, mutect2, varscan2
- SKIDA1 | c.2493G>T p.K831N | Missense Mutation (SNP) | VAF 77/114 reads (68%) | SIFT deleterious (0.03); PolyPhen benign (0.118); catalogued as COSV71610783; called by muse, mutect2, varscan2
- SKIL | c.1901C>T p.A634V | Missense Mutation (SNP) | VAF 26/181 reads (14%) | SIFT deleterious (0.05); PolyPhen benign (0.046); catalogued as COSV52058945; called by mutect2, varscan2
- SLC6A2 | c.1759A>G p.R587G | Missense Mutation (SNP) | VAF 32/75 reads (43%) | SIFT deleterious (0); PolyPhen benign (0.284); catalogued as COSV54914984; called by muse, mutect2, varscan2
- SLC7A8 | c.682G>A p.E228K | Missense Mutation (SNP) | VAF 79/178 reads (44%) | SIFT tolerated (0.65); PolyPhen benign (0.014); catalogued as COSV57553548; called by muse, mutect2, varscan2
- SLITRK2 | c.64C>T p.R22C | Missense Mutation (SNP) | VAF 44/55 reads (80%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.893); catalogued as COSV100158069, COSV59424087; called by muse, mutect2, varscan2
- SOGA1 | c.1558G>A p.E520K | Missense Mutation (SNP) | VAF 4/13 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1442801021, COSV52914628, COSV99414105; called by muse, mutect2, varscan2
- SPATA46 | c.52G>A p.A18T | Missense Mutation (SNP) | VAF 23/112 reads (21%) | SIFT tolerated (0.26); PolyPhen benign (0.018); catalogued as rs200572228; called by muse, mutect2, varscan2
- SPO11 | c.743C>T p.T248M | Missense Mutation (SNP) | VAF 5/46 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs775018422, COSV61994989; called by muse, mutect2
- SULF1 | c.2028C>A p.S676R | Missense Mutation (SNP) | VAF 29/192 reads (15%) | SIFT deleterious (0.05); PolyPhen benign (0.049); catalogued as COSV52677510; called by muse, mutect2, varscan2
- TLCD4-RWDD3 | c.581G>C p.R194P | Missense Mutation (SNP) | VAF 47/169 reads (28%) | PolyPhen benign (0.307); catalogued as COSV55721596, COSV55722281; called by muse, mutect2, varscan2
- TOP3A | c.1643G>A p.R548Q | Missense Mutation (SNP) | VAF 26/90 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as rs151096656; called by muse, mutect2, varscan2
- TPRX1 | c.1003C>T p.P335S | Missense Mutation (SNP) | VAF 10/18 reads (56%) | SIFT tolerated (0.13); PolyPhen benign (0.152); catalogued as COSV100445960; called by muse, mutect2, varscan2
- TPRX1 | c.1002G>T p.W334C | Missense Mutation (SNP) | VAF 10/17 reads (59%) | SIFT tolerated (0.11); PolyPhen benign (0.015); catalogued as COSV100445784; called by muse, varscan2
- TTC17 | c.3008G>A p.R1003Q | Missense Mutation (SNP) | VAF 83/233 reads (36%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.978); catalogued as rs372683087, COSV50006546; called by muse, mutect2, varscan2
- UBE3B | c.2497A>T p.I833F | Missense Mutation (SNP) | VAF 42/130 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV61073561; called by muse, mutect2, varscan2
- VCAN | c.6007G>A p.E2003K | Missense Mutation (SNP) | VAF 13/448 reads (3%) | SIFT tolerated (0.25); PolyPhen benign (0.074); catalogued as rs1482969074, COSV99427696; called by muse, mutect2
- WFIKKN2 | c.1344C>A p.C448* | Nonsense Mutation (SNP) | VAF 15/60 reads (25%) | catalogued as COSV60958290; called by muse, mutect2, varscan2
- ZNF564 | c.469C>T p.R157* | Nonsense Mutation (SNP) | VAF 68/264 reads (26%) | catalogued as rs760900774, COSV59434268; called by muse, mutect2, varscan2
- ZNF781 | c.100G>A p.E34K | Missense Mutation (SNP) | VAF 29/390 reads (7%) | SIFT tolerated (0.47); PolyPhen benign (0.225); catalogued as COSV62201916; called by muse, mutect2
- ZXDB | c.1793G>C p.R598T | Missense Mutation (SNP) | VAF 21/144 reads (15%) | SIFT tolerated (0.11); PolyPhen benign (0.019); catalogued as COSV66492562; called by muse, mutect2, varscan2
- ACSBG1 | c.1620C>T p.I540= | Silent (SNP) | VAF 7/34 reads (21%) | catalogued as rs747882724, COSV51904260; called by muse, mutect2, varscan2
- AUTS2 | c.1788C>T p.P596= | Silent (SNP) | VAF 128/302 reads (42%) | catalogued as COSV61391334; called by muse, mutect2, varscan2
- C1orf100 | c.307C>T p.L103= | Silent (SNP) | VAF 10/170 reads (6%) | catalogued as COSV100353517; called by muse, mutect2
- CC2D1B | c.1609C>T p.L537= | Silent (SNP) | VAF 3/30 reads (10%) | catalogued as COSV99430411; called by muse, mutect2
- CCNL2 | c.135G>A p.V45= | Silent (SNP) | VAF 12/24 reads (50%) | catalogued as COSV61224105; called by muse, mutect2, varscan2
- CCNT2 | c.1479A>G p.K493= | Silent (SNP) | VAF 5/60 reads (8%) | catalogued as COSV99751314; called by muse, mutect2
- CRIM1 | c.471G>A p.Q157= | Silent (SNP) | VAF 17/672 reads (3%) | catalogued as rs1435599830, COSV99753494, COSV99754799; called by muse, mutect2
- HNRNPM | c.1419C>T p.G473= | Silent (SNP) | VAF 29/119 reads (24%) | catalogued as rs754042490, COSV99725924; called by muse, mutect2, varscan2
- KATNIP | c.4491G>T p.V1497= | Silent (SNP) | VAF 57/159 reads (36%) | catalogued as COSV55176657; called by muse, mutect2, varscan2
- KRT17 | c.295C>T p.L99= | Silent (SNP) | VAF 25/44 reads (57%) | catalogued as CD012267, COSV60860365; called by muse, mutect2, varscan2
- LAMA1 | c.3255C>T p.P1085= | Silent (SNP) | VAF 10/49 reads (20%) | catalogued as rs375804587; called by muse, mutect2, varscan2
- LRPPRC | c.2313G>A p.L771= | Silent (SNP) | VAF 45/147 reads (31%) | catalogued as COSV53236230; called by muse, mutect2, varscan2
- NINJ2 | c.153G>A p.K51= | Silent (SNP) | VAF 26/93 reads (28%) | catalogued as rs1345374663, COSV56751208; called by muse, mutect2, varscan2
- NUP214 | c.6272G>A p.*2091= | Silent (SNP) | VAF 50/114 reads (44%) | catalogued as COSV63908459; called by muse, mutect2, varscan2
- OR4D10 | c.306T>C p.F102= | Silent (SNP) | VAF 144/331 reads (44%) | catalogued as COSV73259994; called by muse, mutect2, varscan2
- POMGNT2 | c.1128C>T p.P376= | Silent (SNP) | VAF 13/97 reads (13%) | catalogued as rs571632689, COSV100768179; called by muse, mutect2, varscan2
- PPP6R1 | c.48G>T p.L16= | Silent (SNP) | VAF 40/1532 reads (3%) | catalogued as COSV69799273; called by muse, mutect2
- RBM41 | c.1053C>T p.G351= | Silent (SNP) | VAF 161/259 reads (62%) | catalogued as rs748041481, COSV52562691; called by muse, mutect2, varscan2
- SCPEP1 | c.648G>T p.L216= | Silent (SNP) | VAF 11/160 reads (7%) | catalogued as COSV99227927; called by muse, mutect2
- SLC26A3 | c.1387C>A p.R463= | Silent (SNP) | VAF 90/500 reads (18%) | catalogued as rs386833453, CM115270, COSV100385349, COSV60640682; called by muse, mutect2, varscan2
- TMEM168 | c.1653T>G p.P551= | Silent (SNP) | VAF 94/428 reads (22%) | catalogued as COSV57180039; called by muse, mutect2, varscan2
- TOP1 | c.1417C>A p.R473= | Silent (SNP) | VAF 20/151 reads (13%) | catalogued as rs750868062, COSV100793989, COSV63696151; called by muse, mutect2, varscan2
- TRIM3 | c.747C>T p.G249= | Silent (SNP) | VAF 24/96 reads (25%) | catalogued as COSV100624476, COSV61983452; called by muse, mutect2, varscan2
- WDR17 | c.2724T>A p.V908= | Silent (SNP) | VAF 22/624 reads (4%) | catalogued as COSV99708461; called by muse, mutect2
- ZFP14 | c.435T>C p.I145= | Silent (SNP) | VAF 135/350 reads (39%) | catalogued as COSV54201684; called by muse, mutect2, varscan2
- ZNF521 | c.2178C>T p.L726= | Silent (SNP) | VAF 117/286 reads (41%) | catalogued as COSV64124009, COSV64131384; called by muse, mutect2, varscan2
- C11orf40 | n.297C>A | RNA (SNP) | VAF 106/425 reads (25%) | catalogued as COSV56890210; called by muse, mutect2, varscan2
- OR5AU1 | c.-30T>C | 5'UTR (SNP) | VAF 11/183 reads (6%) | catalogued as COSV100436235; called by muse, mutect2
- TMEM105 | n.727C>A | RNA (SNP) | VAF 5/23 reads (22%) | catalogued as COSV59654901, COSV59654925; called by muse, mutect2
